Gene-level copy-number profile of tumor specimen TCGA-CV-6950-01A from TCGA case TCGA-CV-6950, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,549 days).
Specimen TCGA-CV-6950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a52e4b88-bfac-4d4f-815c-0688f314cdaa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6950-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/086d93d3-2f95-4681-a7fd-695a15560ea0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 200; copy number 2: 4,435; copy number 3: 13,147; copy number 4: 20,598; copy number 5: 9,542; copy number 6: 8,717; copy number 7: 2,899; copy number 8: 101; copy number 10: 38; copy number 12: 2; copy number 14: 15; copy number 17: 62; copy number 20: 17; copy number 30: 44; copy number 51: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6950-01A-11D-1910-01): tumor purity 0.44, ploidy 4.25, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 181 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,340,998, 14 genes, copy number 14 (within-gene range 6–14): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene, copy number 14: TRGV5P.
- chr11:68,683,779–71,252,577, 64 genes, copy number 20–51 (within-gene range 4–51) (broad region; genes not listed).
- chr14:21,667,940–22,506,702, 100 genes, copy number 10–17 (within-gene range 7–17) (broad region; genes not listed).
- chr17:52,862,121–52,987,652, 2 genes, copy number 12: LINC02089, LINC02876.

Autosomal genes at a single copy (total copy number 1): 200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
